Somatic mutation profile of cancer-model specimen HCM-CSHL-0768-C56-85N (3D Organoid, passage 3; aliquot HCM-CSHL-0768-C56-85N-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0768-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage II; Tumor grade: High Grade.
Specimen HCM-CSHL-0768-C56-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c45f51f6-cc7b-4d32-bdd3-7b50887bbeff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0768-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0768-C56-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58e0ef2f-346e-4c0e-86d6-c5de7008f694

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Nonsense Mutation 5, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 240/240 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC5 | c.3799C>T p.R1267* | Nonsense Mutation (SNP) | VAF 215/513 reads (42%) | catalogued as COSV55593485; called by muse, mutect2, varscan2
- ATP10A | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 123/416 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1381646630, COSV63519072; called by muse, mutect2, varscan2
- GRK3 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 303/303 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748016202; called by muse, mutect2, varscan2
- MED30 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 45/556 reads (8%) | catalogued as rs747290267, COSV99815916; called by muse, mutect2
- NPIPB15 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 67/424 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs375786148; called by muse, mutect2, varscan2
- PCNT | c.5266A>G p.M1756V | Missense Mutation (SNP) | VAF 266/585 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs769923170; called by muse, mutect2, varscan2
- PHYKPL | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs757976712, COSV57425767; called by muse, mutect2, varscan2
- RINL | c.1519G>A p.A507T (on ENST00000591812 / NM_001195833.2; = p.A393T on NM_198445.4) | Missense Mutation (SNP) | VAF 313/681 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1173818428; called by muse, mutect2, varscan2
- SAMD9L | c.4016G>A p.R1339K | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as rs1346276637; called by muse, mutect2, varscan2
- AKR7A2 | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 477/767 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ATF6 | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAS1 | c.1660G>A p.G554R | Missense Mutation (SNP) | VAF 175/618 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CCDC86 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 149/228 reads (65%) | called by muse, mutect2, varscan2
- CSMD3 | c.8786A>T p.K2929I (on ENST00000297405 / NM_001363185.1; = p.K2760I on NM_052900.3) | Missense Mutation (SNP) | VAF 156/758 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ECHDC3 | c.847_874del p.G283Rfs*49 | Frame Shift Del (DEL) | VAF 133/311 reads (43%) | called by mutect2, pindel, varscan2
- GOLGA6C | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 105/415 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HAS3 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 23/412 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- IPP | c.577_582del p.S193_I194del | In Frame Del (DEL) | VAF 122/434 reads (28%) | called by mutect2, pindel, varscan2
- MUC5B | c.13823G>T p.S4608I | Missense Mutation (SNP) | VAF 241/893 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 390/756 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAV1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 146/146 reads (100%) | called by muse, mutect2, varscan2
- SRFBP1 | c.1070A>T p.N357I | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TGOLN2 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 31/770 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.094); called by muse, mutect2
- THSD7A | c.337A>T p.K113* | Nonsense Mutation (SNP) | VAF 116/365 reads (32%) | called by muse, mutect2, varscan2
- TNS2 | c.1221G>T p.W407C (on ENST00000314250 / NM_170754.4; = p.W417C on NM_015319.2) | Missense Mutation (SNP) | VAF 289/290 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD3E | c.586C>A p.R196= | Silent (SNP) | VAF 312/468 reads (67%) | called by muse, varscan2
- EFR3A | c.1438T>C p.L480= | Silent (SNP) | VAF 695/886 reads (78%) | called by muse, mutect2, varscan2
- FES | c.1788C>T p.L596= | Silent (SNP) | VAF 133/439 reads (30%) | called by muse, mutect2, varscan2
- HCN3 | c.1290C>T p.A430= | Silent (SNP) | VAF 144/444 reads (32%) | called by muse, mutect2, varscan2
- HTR3D | c.1233C>T p.H411= (on ENST00000382489 / NM_001163646.2; = p.H236= on NM_182537.3) | Silent (SNP) | VAF 174/767 reads (23%) | catalogued as rs550781623; called by muse, mutect2, varscan2
- IL1F10 | c.324C>T p.S108= | Silent (SNP) | VAF 130/463 reads (28%) | catalogued as rs375615196; called by muse, mutect2, varscan2
- OR2A5 | c.783C>A p.A261= | Silent (SNP) | VAF 90/352 reads (26%) | catalogued as COSV68738975; called by muse, mutect2
- R3HCC1L | c.786A>T p.G262= | Silent (SNP) | VAF 271/410 reads (66%) | catalogued as rs1279143201, COSV54404105; called by muse, mutect2, varscan2
- ZNF670 | c.306A>G p.P102= | Silent (SNP) | VAF 244/343 reads (71%) | catalogued as rs763924657; called by muse, mutect2, varscan2
- AP1S3 | c.292-4947G>A | Intron (SNP) | VAF 92/318 reads (29%) | called by muse, mutect2, varscan2
